Surgical pathology report (de-identified scan), TCGA case TCGA-CM-5861, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-5861-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:
Adenocarcinoma of colon.

Specimens Submitted:
1: SP: Colon, right; segmental resection
2: SP: Omentum; omentectomy

DIAGNOSIS:

1. SP: Colon, right; segmental resection:

Tumor Type:

Adenocarcinoma with mucinous features (<50% mucinous component)

Histologic Grade:

Moderately differentiated

Tumor Location:

Cecum

Tumor Size:

Length is 5 cm

Width is 8 cm

Maximal thickness is 0.4 cm

Tumor Budding:

Absent

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubulovillous adenoma

Deepest Tumor Invasion:

Subserosal adipose tissue and/or mesenteric fat

Tumor is seen within 1 mm of the serosal surface in an area of

serositis

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Not identified

Large Venous Invasion:

Not Identified

Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

** Continued on next page **

[page 2 of 3]
Not Identified

Non-Neoplastic Bowel:
Unremarkable

Appendix:

Not identified

Lymph Nodes:

Number with metastasis: 0

Total number examined: 28

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into
pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N0 (No regional lymph node metastasis)

2. OMENTUM, OMENTECTOMY:

-BENIGN MATURE ADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

1). The specimen is received fresh, labeled "Right colon" and consists of a
segment of terminal ileum, cecum, and ascending colon. The appendix is not
grossly identified. The terminal ileum measures 12 cm in length and 4 cm in
circumference at the proximal resected margin. The remaining colon measures
23 in length with a circumference of 7.2 cm at the distal resected margin.
The intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated
yellow tan adipose tissue spans the length of the specimen measuring up to
5.5 cm in thickness. The specimen is opened to reveal a friable, polypoid
mass lesion measuring 5.0 cm in length and 8.0 cm in width. The mass is
located in the large intestine, 14 cm from the proximal margin and 20 cm
from the distal margin. Sectioning shows that the tumor grossly invades
through the muscularis and involves the underlying adipose tissue, and 1.5
cm from the ileocecal valve. The depth of invasion is 0.4 cm grossly. The
ileocecal valve is granular and markedly edematous. The remaining mucosa is
tan-brown with the normal folds. The attached adipose tissue is submitted
for lymph node dissection. Representative sections of the specimen are
submitted for permanent sections and for TPS.

Summary of sections:

P - proximal margin shave

D - distal margin shave

** Continued on next page **

[page 3 of 3]
T - tumor
I--ileocecal valve
RS -representative sections
LN - lymph nodes
BLN - bisected lymph nodes

2). The specimen is received fresh, labeled "Omentum." It consists of a 24 x 8.5 x 0.5 cm portion of lobulated adipose tissue consistent with omentum. Serial sectioning reveals a yellow lobulated surface. No lymph nodes are grossly identified. Representative sections are submitted.

Summary of sections:
O - omentum

Summary of Sections:

Part 1: SP: Colon, right; segmental resection

Block	Sect.	Site	PCs
2		DM	4
2		I	2
10		LN	24
1		PM	2
4		RS	8
11		T	11

Part 2: SP: Omentum; omentectomy

Block	Sect.	Site	PCs
3		O	6

** End of Report **

Source: NCI Genomic Data Commons file a7833d4d-c62c-4557-8efe-cac60fd4c60e (TCGA-CM-5861.AE1EC4F2-2522-4318-9403-1471F2FAB424.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).